Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70Q-01A (Primary Tumor).

[page 1 of 2]
PAGE 1

SURGICAL PATHOLOGY REPORT

Name	Age/Sex	Attend Dr.
Reg	Status	Location
Specimen: Spec Date: Spec Type: SURG PATH Status:		
Rec'd Date: Subm Dr:		
DIAGNOSIS A & B. RETROCARDIAC PARAGANGLIOMA; -NEUROENDOCRINE NEOPLASM CONSISTENT WITH PARAGANGLIOMA, MEASURING 1.3 CM IN THIS SPECIMEN NOTE: THE CELLS STAIN FOR SYNTOPHYSIN. S-100 IS NONCONTRIBUTORY. ON H & E STAINS, THERE IS FAIRLY PROMIENT NUCLEAR PLEOMORPHISM. BIOLOGIC BEHAVIOR CANNOT BE PREDICTED ON THE BASIS OF THE HISTOLOGICAL FINDINGS ALONE. FROZEN SECTION DIAGNOSIS PARAGANGLIOMA RETRO CARDIAC; -CONSISTENT WITH PARAGANGLIOMA PRELIMINARY DIAGNOSIS Cardiac paraganglioma POST-OP DIAGNOSIS Same GROSS DESCRIPTION A. The specimen is received fresh for frozen section labeled "paraganglioma retro cardiac" is an irregular 2 x 1.5 x 1 cm fragment which on cut surface has firm tan areas. A frozen section is performed and the remainder of the specimen is submitted in cassette B. Received in formalin labeled "paraganglioma retrocardiac" and consists of a 2 x 1.5 x 0.6 cm fragments of tissue which on cut surfaces has tan firm areas and is bisected and totally submitted in two cassettes.		

ICD O-3
Paraganglioma, extra-
adrenal NOS 8693/1
Site Thorax NOS C74.0
JW 8/8/13

The information contained in this report is privileged and confidential. If you are
not the intended recipient, disclosure, copying, distribution, or taking of any
action in reliance of its contents is strictly prohibited. If you have received
this in error, please notify us immediately.

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
PAGE 2

SURGICAL PATHOLOGY REPORT

Specimen:

Received:

Status:

Req#:

COPIES TO:

Spec Type:

Subm Dr:

NO PRIMARY CARE MD

NONE

NONE,

REVIEWED AND ELECTRONICALLY SIGNED BY
(Signature on file)

The information contained in this report is privileged and confidential. If you are not the intended recipient, disclosure, copying, distribution, or taking of any action in reliance of its contents is strictly prohibited. If you have received this in error, please notify us immediately.

** END OF REPORT **

HPV Discrepancy		/

Source: NCI Genomic Data Commons file 47303337-ce32-4178-81b1-7cbe01c5dd82 (TCGA-QR-A70Q.57D56938-4A86-41FB-B648-9D3C24E78363.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).